Gene-level copy-number profile of tumor specimen TCGA-XF-AAMZ-01A from TCGA case TCGA-XF-AAMZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 81.2 years (29,667 days).
Specimen TCGA-XF-AAMZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.57f8cf7e-216b-470a-9b60-9c505a262a3d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-AAMZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/24fcbfb5-c4bf-44b2-890e-ef4bff6b924a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 8,079; copy number 3: 45,455; copy number 4: 4,428; copy number 5: 1,216; copy number 6: 335; copy number 7: 50; copy number 8: 71; copy number 9: 61; copy number 10: 17; copy number 11: 5; copy number 12: 5; copy number 19: 57; copy number 22: 10; copy number 31: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-AAMZ-01A-11D-A42D-01): tumor purity 0.3, ploidy 5.87, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 210 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,830,160–161,118,055, 18 genes, copy number 9 (within-gene range 3–9): CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2.
- chr1:161,766,320–162,446,566, 15 genes, copy number 9 (within-gene range 3–9): ATF6, AL391825.1, OLFML2B, AL590408.1, NOS1AP, AL450163.1, MIR4654, AL512785.1, RNA5SP61, MIR556, AL512785.2, SPATA46, C1orf226, SH2D1B, SLAMF6P1.
- chr1:166,387,727–166,490,307, 3 genes, copy number 7: AL583804.1, FMO7P, LINC01675.
- chr1:167,809,386–167,914,215, 1 gene, copy number 9 (within-gene range 3–9): ADCY10.
- chr1:167,916,675–169,630,193, 42 genes, copy number 9–10: MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1, CCDC181, SLC19A2, AL021068.1, Z99572.1, F5, SELP.
- chr1:169,690,665–169,764,705, 2 genes, copy number 10 (within-gene range 3–10): SELL, SELE.
- chr4:79,901,146–81,215,117, 11 genes, copy number 7–11 (within-gene range 4–11): ANTXR2, KPNA2P1, RPSAP39, AC021127.1, PRDM8, FGF5, CFAP299, AC105917.1, BMP3, PRKG2, PRKG2-AS1.
- chr6:19,143,695–20,212,469, 12 genes, copy number 7–12: AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1.
- chr6:21,485,896–22,654,455, 13 genes, copy number 7 (within-gene range 2–7): LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1.
- chr8:99,960,936–101,669,726, 55 genes, copy number 19 (within-gene range 3–19): RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1.
- chr8:101,686,547–101,847,360, 2 genes, copy number 19: AP000426.1, AP001329.1.
- chr11:68,460,731–69,819,416, 36 genes, copy number 22–31: PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
